Somatic mutation profile of tumor specimen 0DM1JZ from CCDI case PBCABN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 13.4 years (4,900 days).
Specimen 0DM1JZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50fe1af3-82ba-4961-a069-8d01fc173c12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM1JF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/819b8f13-58fb-4228-9848-0b8bd99db487

The open-access MAF lists 100 somatic variants for this specimen: 60 protein-altering or splice-affecting, 22 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 22, Nonsense Mutation 9, Intron 8, 5'UTR 6, 5'Flank 2, Splice Region 2, Nonstop Mutation 1, In Frame Del 1, 3'UTR 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 290/710 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD46 | c.696C>G p.I232M | Missense Mutation (SNP) | VAF 224/560 reads (40%) | PolyPhen benign (0); catalogued as rs1220884383; called by muse, mutect2, varscan2
- ATP11B | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 272/680 reads (40%) | catalogued as rs1484320410; called by muse, mutect2, varscan2
- COX11 | c.648+7C>T | Splice Region (SNP) | VAF 192/596 reads (32%) | catalogued as rs780726321; called by muse, mutect2, varscan2
- DMPK | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 64/640 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.061); catalogued as rs773706825; called by muse, mutect2
- DNAH5 | c.9911C>T p.S3304L | Missense Mutation (SNP) | VAF 213/497 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs139821753; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFCAB5 | c.2438C>A p.S813* | Nonsense Mutation (SNP) | VAF 244/651 reads (37%) | catalogued as rs901565647, COSV57935846; called by muse, mutect2, varscan2
- EGFL8 | c.255_266del p.R86_V89del | In Frame Del (DEL) | VAF 74/272 reads (27%) | catalogued as rs754773356; called by mutect2, varscan2
- ERBB2 | c.3628C>A p.P1210T | Missense Mutation (SNP) | VAF 120/422 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV54068542; called by muse, mutect2, varscan2
- ETV3L | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 194/412 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV71901188; called by muse, mutect2, varscan2
- FXR2 | c.1340C>G p.S447* | Nonsense Mutation (SNP) | VAF 130/380 reads (34%) | catalogued as COSV51467756; called by muse, mutect2, varscan2
- GPKOW | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 199/465 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV50242642; called by muse, mutect2, varscan2
- ITGB3BP | c.533G>C p.*178Sext*21 | Nonstop Mutation (SNP) | VAF 144/525 reads (27%) | catalogued as COSV99371307; called by muse, mutect2, varscan2
- ITIH2 | c.1281C>T p.G427= | Splice Region (SNP) | VAF 158/368 reads (43%) | catalogued as rs769442335, COSV100623249, COSV100623445; called by muse, mutect2, varscan2
- MIEN1 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54065114; called by muse, mutect2, varscan2
- NPY1R | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 378/898 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56713197; called by muse, mutect2, varscan2
- NSMAF | c.1527G>C p.W509C | Missense Mutation (SNP) | VAF 289/816 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99232417, COSV99232438; called by muse, mutect2, varscan2
- OTUD7B | c.2427C>G p.F809L | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.472); catalogued as rs1013492701, COSV64915940; called by muse, mutect2, varscan2
- OTX2 | c.76C>A p.H26N | Missense Mutation (SNP) | VAF 132/356 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV59765468; called by mutect2, varscan2
- PPL | c.4982T>C p.I1661T | Missense Mutation (SNP) | VAF 139/357 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776913352; called by muse, mutect2, varscan2
- PSMD8 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 96/226 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV99286512; called by muse, mutect2, varscan2
- RNF149 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 102/227 reads (45%) | catalogued as rs763258401, COSV54865879; called by muse, mutect2, varscan2
- SACS | c.4606G>T p.V1536L | Missense Mutation (SNP) | VAF 246/638 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs764832688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLIT3 | c.1662G>C p.K554N | Missense Mutation (SNP) | VAF 191/466 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV60608393, COSV60634357; called by muse, mutect2, varscan2
- SMARCAD1 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 64/670 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100758661, COSV100758806; called by muse, mutect2
- SNED1 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 122/308 reads (40%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.701); catalogued as rs1043639010, COSV60034693; called by muse, mutect2, varscan2
- SYNE2 | c.12226G>C p.E4076Q | Missense Mutation (SNP) | VAF 266/906 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100646666; called by muse, mutect2, varscan2
- ZFYVE28 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.278); catalogued as rs779521485; called by muse, mutect2, varscan2
- AP5M1 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 156/409 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASPM | c.7867G>A p.E2623K | Missense Mutation (SNP) | VAF 334/842 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CCDC120 | c.1274C>A p.S425* | Nonsense Mutation (SNP) | VAF 107/256 reads (42%) | called by muse, mutect2, varscan2
- CD28 | c.143C>G p.S48* | Nonsense Mutation (SNP) | VAF 65/870 reads (7%) | called by muse, mutect2
- CEACAM3 | c.511G>C p.V171L | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- COL13A1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DUSP12 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 307/669 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ECPAS | c.5026G>T p.E1676* | Nonsense Mutation (SNP) | VAF 218/730 reads (30%) | called by muse, mutect2, varscan2
- ETS1 | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 311/812 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- FAM110C | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FANCM | c.2782C>A p.Q928K | Missense Mutation (SNP) | VAF 229/661 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- GNL2 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 308/733 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- HABP4 | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 174/454 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HR | c.2763C>A p.F921L | Missense Mutation (SNP) | VAF 148/427 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LILRB4 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 67/642 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MED14 | c.349-1G>C p.X117_splice | Splice Site (SNP) | VAF 207/441 reads (47%) | called by muse, mutect2, varscan2
- MGAT4D | c.1105C>G p.Q369E | Missense Mutation (SNP) | VAF 140/410 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MYO16 | c.3160G>A p.D1054N | Missense Mutation (SNP) | VAF 302/742 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NIFK | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 167/352 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- NKX2-8 | c.642C>A p.F214L | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PDZRN4 | c.1634C>T p.S545L (on ENST00000402685 / NM_001164595.2; = p.S287L on NM_013377.4) | Missense Mutation (SNP) | VAF 116/1318 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2
- PHF20L1 | c.949C>G p.Q317E | Missense Mutation (SNP) | VAF 216/542 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PLK2 | c.1174G>C p.D392H | Missense Mutation (SNP) | VAF 272/650 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- PPM1K | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 189/468 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBM27 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 287/695 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RIPK1 | c.555G>T p.K185N | Missense Mutation (SNP) | VAF 232/729 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SETD5 | c.986C>G p.S329* | Nonsense Mutation (SNP) | VAF 78/881 reads (9%) | called by muse, mutect2
- SPDYE1 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STRC | c.4075G>C p.E1359Q | Missense Mutation (SNP) | VAF 198/462 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TTN | c.85246G>C p.D28416H (on ENST00000591111; = p.D20992H on NM_003319.4) | Missense Mutation (SNP) | VAF 311/765 reads (41%) | PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- VPS50 | c.1653G>C p.K551N | Missense Mutation (SNP) | VAF 219/600 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZMYM2 | c.1943C>G p.S648* | Nonsense Mutation (SNP) | VAF 216/760 reads (28%) | called by muse, mutect2, varscan2
- ANO3 | c.168C>G p.L56= | Silent (SNP) | VAF 310/818 reads (38%) | called by muse, mutect2, varscan2
- ARMC7 | c.189C>T p.L63= | Silent (SNP) | VAF 228/564 reads (40%) | catalogued as rs1222496754; called by muse, mutect2, varscan2
- CACNA1C | c.1875G>A p.L625= | Silent (SNP) | VAF 219/783 reads (28%) | called by muse, mutect2, varscan2
- ENTPD2 | c.1281G>A p.K427= (on ENST00000355097 / NM_203468.3; = p.K404= on NM_001246.4) | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs764416173; called by muse, mutect2, varscan2
- EPHB4 | c.276C>T p.F92= | Silent (SNP) | VAF 117/245 reads (48%) | catalogued as rs773921574; called by muse, mutect2, varscan2
- FBXW5 | c.516C>T p.V172= | Silent (SNP) | VAF 117/324 reads (36%) | called by muse, mutect2, varscan2
- GASK1A | c.414G>A p.L138= | Silent (SNP) | VAF 196/433 reads (45%) | catalogued as COSV56183613; called by muse, mutect2, varscan2
- HPS5 | c.942C>T p.F314= (on ENST00000349215 / NM_181507.2; = p.F200= on NM_007216.4) | Silent (SNP) | VAF 228/673 reads (34%) | called by muse, mutect2, varscan2
- KMT2C | c.11343G>A p.L3781= | Silent (SNP) | VAF 71/750 reads (9%) | called by muse, mutect2
- MMP11 | c.387G>A p.T129= | Silent (SNP) | VAF 289/648 reads (45%) | catalogued as rs370558216; called by muse, mutect2, varscan2
- MTUS2 | c.1143G>A p.K381= | Silent (SNP) | VAF 117/417 reads (28%) | catalogued as rs753807402; called by muse, mutect2, varscan2
- OR8J3 | c.753C>T p.F251= | Silent (SNP) | VAF 279/757 reads (37%) | catalogued as rs1217601575, COSV100040742, COSV100040856; called by muse, mutect2, varscan2
- POTEH | c.1389T>C p.H463= | Silent (SNP) | VAF 171/880 reads (19%) | catalogued as rs772987891; called by muse, mutect2, varscan2
- RDH10 | c.153C>G p.L51= | Silent (SNP) | VAF 77/205 reads (38%) | called by muse, mutect2, varscan2
- RNF41 | c.210G>C p.R70= | Silent (SNP) | VAF 181/502 reads (36%) | called by muse, mutect2, varscan2
- SLC27A3 | c.1026C>T p.G342= (on ENST00000271857; = p.G214= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 104/262 reads (40%) | catalogued as rs1473802741; called by muse, mutect2, varscan2
- STARD13 | c.2304G>A p.L768= (on ENST00000336934 / NM_001243476.3; = p.L650= on NM_052851.3) | Silent (SNP) | VAF 182/548 reads (33%) | called by muse, mutect2, varscan2
- SYNE3 | c.261G>T p.L87= | Silent (SNP) | VAF 172/372 reads (46%) | called by muse, mutect2, varscan2
- SYVN1 | c.876C>A p.I292= | Silent (SNP) | VAF 209/529 reads (40%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.1383C>T p.L461= | Silent (SNP) | VAF 61/567 reads (11%) | called by muse, varscan2
- ZNF367 | c.417C>G p.L139= | Silent (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- ZYG11B | c.2031C>G p.V677= | Silent (SNP) | VAF 189/597 reads (32%) | called by muse, mutect2, varscan2
- AC233702.8 | chr17:21551000 G>A | 5'Flank (SNP) | VAF 155/397 reads (39%) | called by muse, mutect2, varscan2
- ALPK3 | c.-45G>C | 5'UTR (SNP) | VAF 45/80 reads (56%) | called by muse, mutect2, varscan2
- B3GNT4 | c.66+9C>G | Intron (SNP) | VAF 106/220 reads (48%) | called by muse, varscan2
- BCORL1 | c.4306-2822C>G | Intron (SNP) | VAF 112/545 reads (21%) | catalogued as COSV99498132; called by muse, mutect2, varscan2
- CFAP99 | c.207-53C>G | Intron (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2
- DHRS2 | c.421-1494C>T | Intron (SNP) | VAF 123/283 reads (43%) | catalogued as rs1417109111; called by muse, mutect2, varscan2
- DUSP22 | c.-67C>G | 5'UTR (SNP) | VAF 103/200 reads (52%) | called by muse, mutect2, varscan2
- KCNJ3 | c.-31C>T | 5'UTR (SNP) | VAF 112/299 reads (37%) | catalogued as rs766729628, COSV54536084, COSV99715020; called by muse, mutect2, varscan2
- LASP1 | c.165-20C>T | Intron (SNP) | VAF 132/265 reads (50%) | catalogued as rs1050266431; called by muse, mutect2, varscan2
- MPDU1 | chr17:7592663 C>G | 3'Flank (SNP) | VAF 146/367 reads (40%) | called by muse, mutect2, varscan2
- PC | c.*37C>T | 3'UTR (SNP) | VAF 50/121 reads (41%) | called by muse, mutect2, varscan2
- PDHA1 | c.-27C>T | 5'UTR (SNP) | VAF 31/172 reads (18%) | called by muse, mutect2, varscan2
- RBM19 | c.2069-39G>C | Intron (SNP) | VAF 164/403 reads (41%) | catalogued as rs879614741; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43301982 C>G | 5'Flank (SNP) | VAF 134/348 reads (39%) | called by muse, mutect2, varscan2
- SENP3 | c.1263+30G>C | Intron (SNP) | VAF 115/274 reads (42%) | called by muse, mutect2, varscan2
- SLC27A1 | c.-15C>G | 5'UTR (SNP) | VAF 24/191 reads (13%) | called by muse, mutect2, varscan2
- SPRING1 | c.421-80C>G | Intron (SNP) | VAF 106/244 reads (43%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.-5C>T | 5'UTR (SNP) | VAF 53/112 reads (47%) | catalogued as rs749170122; called by muse, mutect2, varscan2
